Somatic mutation profile of tumor specimen C3N-03188-02 (aliquot CPT0207030009) from CPTAC case C3N-03188, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 54.4 years (19,856 days).
Specimen C3N-03188-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0512cb3e-fcc6-49c3-af1e-8275650f0d0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03188-31 (Blood Derived Normal), aliquot CPT0207080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c348712-629f-49df-a9f4-90840d5b28ef

The open-access MAF lists 63 somatic variants for this specimen: 40 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Intron 3, Nonsense Mutation 3, 5'UTR 2, Frame Shift Del 2, RNA 2, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB11 | c.766C>T p.R256C | Missense Mutation (SNP) | VAF 69/198 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1007517047, COSV60355345; called by muse, mutect2, varscan2
- COL27A1 | c.1517C>T p.T506M | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1290281761, COSV61926227; called by muse, mutect2, varscan2
- DNAH11 | c.11041G>A p.V3681M | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs371617349; ClinVar: uncertain significance; called by muse, mutect2
- E2F8 | c.2474G>A p.R825H | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.139); catalogued as rs370899212; called by muse, mutect2, varscan2
- ELFN1 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs1352291996; called by muse, mutect2, varscan2
- GTF2F1 | c.1357C>T p.Q453* | Nonsense Mutation (SNP) | VAF 94/398 reads (24%) | catalogued as COSV55532938; called by muse, mutect2, varscan2
- IRF6 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 50/166 reads (30%) | catalogued as CD022553, CM067420, CM090291; called by muse, mutect2, varscan2
- KCNH8 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376188228; called by muse, mutect2, varscan2
- KLHDC9 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 126/392 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63510420; called by muse, mutect2, varscan2
- LTBR | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748787501; called by muse, mutect2
- MAGEA12 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 138/436 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV63294474; called by muse, mutect2, varscan2
- MGAM2 | c.3109C>A p.R1037S | Missense Mutation (SNP) | VAF 35/184 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.818); catalogued as rs576318860; called by muse, mutect2, varscan2
- OR52H1 | c.937A>G p.T313A (on ENST00000322653; = p.T319A on NM_001005289.1) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs757530661; called by muse, mutect2, varscan2
- OR8H2 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57947047; called by muse, mutect2
- PTGFR | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs145816454, COSV66114518; called by muse, mutect2, varscan2
- PTPRR | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1431973794, COSV51728258; called by muse, mutect2, varscan2
- RAB6B | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 19/402 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs749807184, COSV53312118; called by muse, mutect2
- RYR3 | c.14123G>A p.C4708Y (on ENST00000389232; = p.C4709Y on NM_001036.6) | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66781952; called by muse, mutect2, varscan2
- SERPINI2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 20/138 reads (14%) | catalogued as rs755418313, COSV52984411; called by muse, mutect2
- TF | c.1615G>A p.A539T | Missense Mutation (SNP) | VAF 68/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369813809; called by muse, mutect2, varscan2
- TMEM132C | c.758G>A p.R253H | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.391); catalogued as rs1024188659, COSV70660677; called by muse, mutect2, varscan2
- TMPRSS9 | c.1456G>A p.A486T (on ENST00000648592; = p.A452T on NM_182973.2) | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373647105; called by muse, mutect2, varscan2
- TNRC18 | c.4450del p.R1484Gfs*19 | Frame Shift Del (DEL) | VAF 76/558 reads (14%) | catalogued as rs1562549753, COSV68167632; called by mutect2, pindel, varscan2
- TRIM56 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); catalogued as rs546901188, COSV60158917, COSV60160846; called by muse, mutect2
- ATRX | c.3021A>C p.Q1007H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- C2CD5 | c.3002G>C p.*1001Sext*11 | Nonstop Mutation (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- DAPK1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FCHO1 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRA3 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HOXD11 | c.680A>T p.K227M | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- LYPD6B | c.9T>A p.Y3* (on ENST00000409029 / NM_001317004.1; = p.Y27* on NM_177964.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2
- MAGEB10 | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NCAPG2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 63/242 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- NYAP2 | c.555del p.E185Dfs*19 | Frame Shift Del (DEL) | VAF 21/70 reads (30%) | called by mutect2, pindel, varscan2
- PCDH11Y | c.3142G>T p.V1048F | Missense Mutation (SNP) | VAF 7/246 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); called by muse, mutect2
- SLITRK4 | c.22A>C p.I8L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2
- STOML3 | c.844G>T p.D282Y | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SYNDIG1L | c.438G>T p.E146D | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TACR3 | c.442C>A p.H148N | Missense Mutation (SNP) | VAF 157/479 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- ZP4 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 80/223 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACAA1 | c.21G>T p.V7= | Silent (SNP) | VAF 57/465 reads (12%) | catalogued as COSV57176998; called by muse, mutect2, varscan2
- BEND6 | c.837A>G p.K279= | Silent (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- BPIFB4 | c.1215G>A p.P405= | Silent (SNP) | VAF 120/421 reads (29%) | catalogued as rs200333820, COSV64952159; called by muse, mutect2, varscan2
- CACNA1F | c.5907C>T p.D1969= | Silent (SNP) | VAF 77/222 reads (35%) | catalogued as rs782497299, COSV54297341; called by muse, mutect2, varscan2
- CCL28 | c.18C>T p.L6= | Silent (SNP) | VAF 35/189 reads (19%) | catalogued as rs761593376; called by muse, mutect2, varscan2
- DMD | c.183A>G p.K61= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as CD148449; called by muse, mutect2
- FABP1 | c.117G>A p.S39= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs770387493, COSV55557805; called by muse, mutect2, varscan2
- GRM8 | c.1614T>C p.C538= | Silent (SNP) | VAF 32/406 reads (8%) | called by muse, mutect2
- HMGXB3 | c.1707A>C p.T569= (on ENST00000613459; = p.T323= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 67/277 reads (24%) | called by muse, mutect2, varscan2
- PCDHA10 | c.1539C>T p.S513= | Silent (SNP) | VAF 262/1305 reads (20%) | called by muse, mutect2, varscan2
- PCDHA3 | c.1554C>T p.Y518= | Silent (SNP) | VAF 275/1311 reads (21%) | catalogued as rs957021626; called by muse, mutect2, varscan2
- PLCXD2 | c.444G>A p.S148= | Silent (SNP) | VAF 97/328 reads (30%) | catalogued as rs751872957, COSV67339109; called by muse, mutect2, varscan2
- RIMBP2 | c.1275C>T p.N425= | Silent (SNP) | VAF 183/600 reads (31%) | catalogued as rs150377943, COSV55471554; called by muse, mutect2, varscan2
- TMEM125 | c.528C>T p.C176= | Silent (SNP) | VAF 147/499 reads (29%) | catalogued as rs780801369; called by muse, mutect2, varscan2
- TMEM132D | c.1353G>T p.P451= | Silent (SNP) | VAF 33/329 reads (10%) | catalogued as rs150876325; called by muse, mutect2, varscan2
- TNNT3 | c.597C>T p.I199= (on ENST00000397301 / NM_001367846.1; = p.I188= on NM_006757.4) | Silent (SNP) | VAF 148/533 reads (28%) | catalogued as rs375848299, COSV53484823; called by muse, mutect2, varscan2
- AC005400.1 | n.179-2801C>T | Intron (SNP) | VAF 22/220 reads (10%) | catalogued as rs200965661; called by muse, mutect2, varscan2
- ADGRE4P | n.2197C>A | RNA (SNP) | VAF 7/146 reads (5%) | called by muse, mutect2
- HERC2P2 | n.680T>A | RNA (SNP) | VAF 35/123 reads (28%) | called by mutect2, varscan2
- IGHV3-38 | c.-36C>A | 5'UTR (SNP) | VAF 65/249 reads (26%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-2858G>A | Intron (SNP) | VAF 14/362 reads (4%) | catalogued as rs1352039418; called by muse, mutect2
- SLAMF9 | c.-17G>A | 5'UTR (SNP) | VAF 85/261 reads (33%) | catalogued as rs1236603442; called by muse, mutect2, varscan2
- TTLL10 | c.-28+1484C>T | Intron (SNP) | VAF 192/947 reads (20%) | catalogued as rs1441477360; called by muse, mutect2, varscan2
